Surgical pathology report (de-identified scan), TCGA case TCGA-50-5935, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5935-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

The left upper division segmentectomy demonstrates a 3.0 cm moderately differentiated adenocarcinoma with papillary differentiation arising in a scar. There is no evidence of visceral pleural or angiolymphatic invasion. All sampled lymph nodes are benign. Surgical resection margins are free of tumor. Pathologic stage: T1N0Mx.

PART 1: LUNG, LEFT UPPER LOBE, ENDOBRONCHIAL BIOPSY –
UNREMARKABLE RESPIRATORY MUCOSA.

PART 2: LYMPH NODE, LEVEL 11, BIOPSY -
SIX (6) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 3: LUNG, LEFT UPPER DIVISION, SEGMENTECTOMY –
A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH PAPILLARY DIFFERENTIATION (3.0 CM IN DIAMETER) ARISING IN A SCAR. NO EVIDENCE OF VISCERAL PLEURAL OR ANGIOLYMPHATIC INVASION. MILD LYMPHOCYTIC HOST RESPONSE. PATHOLOGIC STAGE: T1N0MX.
B. SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
C. BACKGROUND LUNG WITH EMPHYSEMATOUS CHANGE AND RESPIRATORY BRONCHIOLITIS.

PART 4: LYMPH NODE, LEVEL 5, BIOPSY -
ONE (1) LYMPH NODE WITH ANTHRACOTIC PIGMENT.

ADDENDA:

Addendum

Fluorescence in-situ hybridization studies performed on the adenocarcinoma shows a ratio of *EGFR* gene to the centromere of chromosome 7 of 1.0 indicating no *EGFR* amplification in the targeted region. The rate of hyperploidy for the centromere of chromosome 7 was 7.1% of the analyzed cells. The signal to nucleus ratio (SNR) for the *EGFR* gene was 1.6.

Interpretation guidelines for *EGFR* Gene Copy Number by FISH:

Ratio of *EGFR* to the centromere of chromosome 7:

Less than 2.0: No *EGFR* amplification

Greater than 2.0: *EGFR* amplification

Hyperploidy: Greater than two centromere copies/cell.

SNR: The average number of *EGFR* signals per analyzed cell within the targeted region.

Clinical studies show high *EGFR* gene copy number by FISH analysis to be associated with favorable clinical benefit (clinical response, stable disease, time to progression, and survival) in patients with advanced non-small cell lung cancer treated with *EGFR* tyrosine kinase inhibitors.

[page 2 of 2]
CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION: Left Upper Lobe
LUNG SEGMENT(S) INVOLVED: Superior
PROCEDURE: Segmental
TUMOR SIZE: Maximum dimension: 3 cm
Minor dimension: 3 cm
GROSS SATELLITES: Number of gross satellite lesions: 0
TUMOR TYPE: Invasive adenocarcinoma
HISTOLOGIC GRADE: G2, Moderately differentiated
MICROSCOPIC SATELLITES: Number of microscopic satellite lesions: 0
EXTRAPULMONARY PARENCHYMAL
EXTENSION/INVASION OF TUMOR: None identified
ANGIOLYMPHATIC INVASION: No
TUMOR NECROSIS: < or = to 50%
SURGICAL MARGIN INVOLVEMENT: No
SURGICAL MARGIN SITE: Distance of invasive tumor to closest margin: 50 mm, Bronchial margin
INFLAMMATORY(DESMOPLASTIC) REACTION: Mild
N1 LYMPH NODES: Number of N1 lymph nodes positive: 0
Number of N1 lymph nodes examined: 6
N2 LYMPH NODES: Number of N2 lymph nodes positive: 0
Number of N2 lymph nodes examined: 1
EXTRACAPSULAR SPREAD OF N2 METASTASES: No
UNDERLYING DISEASE(S): Emphysema, Parenchymal scar, Smokers bronchiolitis
T STAGE, PATHOLOGIC: pT1
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
ANCILLARY STUDIES: Histochemical stains, FISH studies, Molecular studies

SPECIAL PROCEDURES:

Microdissection Genotyping

Interpretation

Molecular Anatomic Pathology testing:

- A. KRAS Exon 1 mutation not identified
- B. EGFR Exon 19 mutation IDENTIFIED (15 bp deletion)
- C. EGFR Exon 21 mutation not identified

Note:

EGFR mutations are present in about 10% of [REDACTED] and up to 40% in the [REDACTED] population. EGFR mutations are not thought to occur in high prevalence in other types of tumors (3,4,7). KRAS mutations are also found in approximately 30% lung adenocarcinomas, but not in combination with EGFR mutations, which implies different pathogenic mechanisms (2,3). The presence of these mutations may have prognostic and or therapeutic implications (1,5,6).

Results

Sample Preparation

For cytology samples, extraction of DNA was performed from the fluid or sample provided. For surgical specimens, microdissection was performed to include neoplastic tissue and normal adjacent tissue. Optical density readings were obtained.

Gene Sequencing

PCR was performed using primers that flank exon 1 in the KRAS gene and exon 19 and 21 of the EGFR gene. Analysis of the PCR products was first performed for the EGFR 19 to detect aberrant length PCR product. A sequencing analysis, using the BigDye Terminator Kit (Applied Biosystems, Inc.) was then performed. The known hotspots were analyzed for the presence of mutations. Both forward and the reverse sequencing was performed.

Source: NCI Genomic Data Commons file d9b8eadf-471e-4f1d-8b4c-f5695a7f379d (TCGA-50-5935.B6F8E549-CB8E-4E6D-8CFE-2DF2B1D57646.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).